Somatic mutation profile of tumor specimen TCGA-AB-2945-03A (aliquot TCGA-AB-2945-03A-01W-0733-08) from TCGA case TCGA-AB-2945, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.7 years (23,984 days).
Specimen TCGA-AB-2945-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4263ab8-fb30-4b74-a4c1-ec14031dc9a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2945-11A (Solid Tissue Normal), aliquot TCGA-AB-2945-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef03a20b-3f0b-49b0-96ae-9791751b8dc0

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLB1L2 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs149988613; called by muse, mutect2, varscan2
- SPACA1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); catalogued as rs373094172, COSV99389783; called by muse, mutect2, varscan2
- TRAM1L1 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs749883628, COSV60291767; called by muse, mutect2, varscan2
